Gene-level copy-number profile of tumor specimen TCGA-3B-A9HI-01A from TCGA case TCGA-3B-A9HI, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 68.4 years (24,984 days).
Specimen TCGA-3B-A9HI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.60785c89-6561-4826-a79a-d024e58aa15d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3B-A9HI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fac0235e-4ab1-490e-9f9f-aa81bd4af648

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 66; copy number 1: 1,389; copy number 2: 14,585; copy number 3: 17,581; copy number 4: 19,551; copy number 5: 2,637; copy number 6: 2,625; copy number 7: 588; copy number 8: 110; copy number 9: 302; copy number 10: 292; copy number 11: 81; copy number 13: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3B-A9HI-01A-11D-A386-01): tumor purity 0.55, ploidy 3.33, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 66 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,751,512–87,863,533, 4 genes: ATAD1, CFL1P1, RN7SL78P, KLLN.
- chr13:48,303,744–48,599,436, 1 gene (within-gene range 0–3): RB1.
- chr13:48,389,567–51,200,252, 61 genes (within-gene range 0–3) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 676 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:156,404,250–163,923,873, 281 genes, copy number 10 (broad region; genes not listed).
- chr1:165,400,922–173,064,015, 180 genes, copy number 9–11 (within-gene range 7–11) (broad region; genes not listed).
- chr9:78,589,158–83,829,516, 57 genes, copy number 9 (within-gene range 8–9): AL592221.1, MTND2P8, KRT18P24, AL512634.1, CHCHD2P9, LNCARSR, TLE4, AL161912.3, NPAP1P6, AL161912.1, AL161912.2, AL161912.4, AL161782.1, LINC01507, NPAP1P4, MTCO1P51, MTND2P9, RPS19P6, AL138749.1, RPS20P25, AL161727.1, TLE1, AL591368.1, RNU6-1035P, RNA5SP287, AL158154.1, SPATA31D5P, AL158154.2, SPATA31D4, AL158154.3, SPATA31D3, SPATA31D2P, AL162726.3, SPATA31D1, SPATA31B1P, DDX10P2, AL158047.1, AL162726.1, MTCO3P40, AL162726.2, AL162726.4, AL356490.1, AL353774.1, RPS6P12, RASEF, AL499602.1, RN7SKP242, AL137847.3, AL137847.1, FRMD3, AL137847.2, RNU4-29P, RNU4-15P, IDNK, UBQLN1, AL354920.1, GKAP1.
- chr11:12,261,426–12,535,356, 3 genes, copy number 9 (within-gene range 6–9): AC079329.1, AC025300.1, PARVA.
- chr11:16,613,132–20,121,601, 100 genes, copy number 9–13 (within-gene range 6–13) (broad region; genes not listed).
- chr11:20,574,186–21,843,210, 11 genes, copy number 10: HMGB1P40, AC090707.2, SLC6A5, NELL1, AC090707.1, RNA5SP336, AC090857.1, AC090857.2, AC099730.1, RNA5SP337, AC130307.1.
- chr11:26,559,032–26,723,427, 2 genes, copy number 9: MUC15, SLC5A12.
- chr21:24,840,550–27,143,949, 42 genes, copy number 9: LINC01692, AP000402.1, AP000146.1, AP001342.1, AP000235.1, AP000233.2, RN7SKP236, AP000233.1, AP001341.1, RNA5SP489, RPL13AP7, AP001340.1, LINC00158, AP000221.1, MIR155HG, MIR155, AP000223.1, MRPL39, JAM2, RNGTTP1, AP000224.1, FDX1P2, ATP5PF, GABPA, LLPHP2, APP, AP001442.1, RNU6-123P, AP001439.1, AP000229.1, RNU6-926P, AP001595.2, AP001595.1, AP001596.1, CYYR1-AS1, AP001596.2, CYYR1, ADAMTS1, AP001599.1, ADAMTS5, MIR4759, GPX1P2.

Autosomal genes at a single copy (total copy number 1): 865. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
